Surgical pathology report (de-identified scan), TCGA case TCGA-A7-A4SA, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Christiana Healthcare, specimen TCGA-A7-A4SA-01A (Primary Tumor).

[page 1 of 2]
Final Surgical Pathology Report

Procedure:

Diagnosis

- A. Sentinel lymph node #1, biopsy: One lymph node with metastatic carcinoma (1/1).
- B. Breast, left, mastectomy: Invasive pleomorphic lobular carcinoma, size 2.2 cm in greatest dimension; negative margins of excision.
- C. Breast, left nipple core, biopsy: Negative for malignancy.
- D. Lymph nodes, left axilla, lymph node dissection: Nine negative lymph nodes (0/9).

Microscopic Description:

Invasive carcinoma:

Histologic type: Lobular (E-cadherin negative)

Histologic grade: 2 (pleomorphic lobular)

Overall grade: 7/9

Architectural score: 3

Nuclear score: 3 (focally - the tumor consists of a mixture of conventional and pleomorphic lobular carcinoma, with nuclear grade ranging from 1-3)

Mitotic score: 1

Greatest dimension (pT2): 2.2 cm

Specimen margins: Invasive carcinoma is 2 mm from the anterior margin, and there is lobular carcinoma in-situ (nuclear grade 1-2) focally 0.5 mm from the anterior margin. Carcinoma is 1 cm from the deep margin.

Vessel invasion: Not identified

Ductal carcinoma in situ: Not identified

Comments: Prior biopsy site identified within the tumor

Lymph nodes: Keratin staining performed on negative lymph node blocks to confirm the absence of carcinoma.

Number of positive nodes of total: One of ten lymph nodes with metastatic carcinoma (1/10)

Size of largest metastasis: 7 mm

Extracapsular extension (present/absent): Negative

pN1a

Prognostic markers: See previous core biopsy,

Specimen

- A. Left axillary sentinel node #1, hot, blue
- B. Left breast, stitch at 12:00
- C. Left nipple core
- D. Left axillary contents

Clinical Information
Left breast cancer

Intraoperative Consultation

A) Metastatic carcinoma.

CFS: Nipple, core biopsy: No evidence of invasive carcinoma.

ICB-0-3

carcinoma, infiltrating lobules, NOS
8520/3

Site: breast, NOS C50.9

lw
10/27/12

[page 2 of 2]
Gross Description

A. Received unfixed for frozen section, labeled left axillary sentinel node #1, hot, blue, is a fat-replaced lymph node, 2.0 x 1.0 x 0.7 cm, bisected and frozen in two blocks.

B. Received unfixed, labeled with the patient's name, medical record number and "left breast - stitch at 12:00." The specimen consists of a nipple sparing simple mastectomy oriented by a stitch at the 12:00 position. The specimen is 14 x 14 x 3.5 cm. The deep surgical margin is painted black and anterior margin over tumor is painted green. On cut section at the 6:00 position there is a firm spiculated tan tumor mass which measures 2.2 x 1.8 x 1.5 cm. A portion is submitted for tissue procurement. The tissue surrounding the mass contains dense fibrocystic changes. The mass comes within 4 mm of the anterior margin and 1.5 cm of the deep margin. The remainder of the breast tissue consists of firm fibrofatty tissue. Representative sections. BLOCK SUMMARY 1-3: Tumor mass with anterior margin, 4: Deep margin nearest tumor, 5, 6: Breast tissue immediately adjacent to the tumor mass, 7: Upper inner quadrant, 8: Lower inner quadrant, 9: Upper outer quadrant, 10: Lower outer quadrant

C. Container C. is labeled with the patient's name, medical record number and "left nipple core". The specimen consists of a single piece of soft yellow tissue measuring 0.5 x 0.5 x 0.3 cm. All submitted in

D. Received fresh labeled "left axillary contents" is a 5.7 x 3.9 x 1.7 cm aggregate of soft, lobulated tan gold adipose tissue. Several slightly rubbery tan-pink-red tissues in keeping with lymph nodes measuring up to 1.9 cm are recovered. The lymphoid tissues are entirely submitted. Summary: 1 - 4 lymph nodes, 2 - 3 lymph nodes, 3 and 4 - one lymph node per cassette

Source: NCI Genomic Data Commons file e868abb5-72e4-48c3-92a6-b77e1b66d308 (TCGA-A7-A4SA.2649764C-9566-49DB-B8E9-B4B86DBB763C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).